Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A7R4, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A7R4-01A (Primary Tumor).

FCD-G-3
Astrocytoma, grade III 9401/3
Site ^{CNS} Brain, supratentorial NOS C71.0
^{V2th} Brain NOS C71.9
9/27/13

Untranslated original report
is housed at the BCR.

astrocytic differentiation

Diagnosis: anaplastic astrocytoma WHO grade III

9. Sept. 2013
WHLj

Source: NCI Genomic Data Commons file 24f2d210-a8d9-43f2-a780-b3d801fe1e6b (TCGA-S9-A7R4.6AE37879-1BB7-4C4A-B318-D9F2D75B552C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).